Somatic mutation profile of tumor specimen PCProject_0445_T2_WES (aliquot PCProject_0445_T2_WES_1) from CMI case PCProject_0445, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.8 years (20,366 days).
Specimen PCProject_0445_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71bc9c36-c304-4fc7-a87a-75f8f53bc636.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0445_SALIVA (DNA), aliquot PCProject_0445_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75ccc247-f809-4790-84ff-f3867f46ad0a

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 41/159 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51644190, COSV51644993, COSV51646200; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 106/697 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs1426323536, COSV99225449; called by muse, mutect2, varscan2
- BEND6 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs371013253; called by muse, mutect2
- CDK12 | c.2752G>C p.D918H | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71002155; called by muse, mutect2, varscan2
- DHX15 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 73/647 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.022); catalogued as rs1196057736; called by muse, mutect2, varscan2
- EP300 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs149456776, COSV54330438; ClinVar: not provided; called by muse, mutect2, varscan2
- GLDN | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs746170404; called by muse, mutect2, varscan2
- NOTCH1 | c.2900A>G p.Y967C | Missense Mutation (SNP) | VAF 218/1249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433433969; called by muse, mutect2, varscan2
- TAS1R3 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 104/678 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs770681591; called by muse, mutect2, varscan2
- UNC5CL | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 98/747 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs529775453, COSV99770770; called by muse, mutect2, varscan2
- APAF1 | c.842_843insA p.V282Cfs*12 (on ENST00000551964 / NM_181861.2; = p.V271Cfs*12 on NM_001160.3) | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- BEND3 | c.2076G>C p.E692D | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CFAP46 | c.7517T>G p.V2506G | Missense Mutation (SNP) | VAF 72/510 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FRMD3 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NKTR | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NRXN1 | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- OR2L13 | c.788A>T p.N263I | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAK2 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AVIL | c.99C>T p.A33= | Silent (SNP) | VAF 54/634 reads (9%) | called by muse, mutect2
- CTC1 | c.3288A>G p.A1096= | Silent (SNP) | VAF 23/528 reads (4%) | called by muse, mutect2
- MRTFA | c.393T>A p.R131= | Silent (SNP) | VAF 49/355 reads (14%) | called by muse, mutect2, varscan2
- SLC38A1 | c.324G>A p.L108= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- ST18 | c.1003C>T p.L335= | Silent (SNP) | VAF 69/254 reads (27%) | called by muse, mutect2, varscan2
- FBXL19 | chr16:30923193 A>G | 5'Flank (SNP) | VAF 188/777 reads (24%) | called by muse, mutect2, varscan2
- KLC1 | c.1651-7068T>G | Intron (SNP) | VAF 69/540 reads (13%) | called by muse, mutect2, varscan2
